MMRF case MMRF_1695 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a68c53af-4359-4f9c-b9cd-de61a62bb922

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.4 years (22,436 days); ISS stage: III; Days to last known disease status: 637 days (1.7 years); Days to last follow up: 637 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 144 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 214 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 198 days; Days to treatment end: 198 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 198 days; Days to treatment end: 198 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 471 days (1.3 years); Days to treatment end: 500 days (1.4 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 637.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -21: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 72.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.76 mg/dL; Immunoglobulin G 4.17 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 8.14 µg/mL; Hemoglobin 5.21 mmol/L; Leukocytes 9.8 ×10⁹/L; Absolute Neutrophil 7.9 ×10⁹/L; Platelets 305 ×10⁹/L; Creatinine 380 µmol/L; Blood Urea Nitrogen 29.3 mmol/L; Calcium 2.13 mmol/L; Albumin 26 g/L; Total Protein 4.5 g/dL; Glucose 7.76 mmol/L.
- Day 48 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 29.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Beta 2 Microglobulin 18.5 µg/mL; Hemoglobin 6.26 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 7.2 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 380 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.05 mmol/L; Albumin 27 g/L; Total Protein 4.7 g/dL; Glucose 4.95 mmol/L.
- Day 144 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.82 mg/dL; Immunoglobulin G 3.98 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 23.3 µg/mL; Hemoglobin 7.32 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 380 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 5.2 g/dL; Glucose 4.9 mmol/L.
- Day 237 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.37 mg/dL; Immunoglobulin G 5.02 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 20.3 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 5.05 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 327 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 6.11 mmol/L.
- Day 335 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.07 mg/dL; Immunoglobulin G 8.51 g/L; Immunoglobulin A 2.01 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 22.4 µg/mL; Hemoglobin 6.94 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 327 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 5.56 mmol/L.
- Day 420 (ECOG 1): Hemoglobin 6.51 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.66 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 368 µmol/L; Blood Urea Nitrogen 17.1 mmol/L.
- Day 502 (ECOG 1): Lactate Dehydrogenase 4.28 µkat/L.

Other clinical attributes
- Day -21: Weight: 79 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1695_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -21 days.
- Sample MMRF_1695_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -21 days.
